FM case AD9120 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/80cf9ef6-ceaa-4cb4-85bf-55378c4b9830

Male, 75.4 years: Carcinoma, NOS (ICD-O-3 8010/3) of the bladder; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
